Somatic mutation profile of tumor specimen C3L-00563-03 (aliquot CPT0063250009) from CPTAC case C3L-00563, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 62.4 years (22,777 days).
Specimen C3L-00563-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f43cb0b-9261-4c98-9e0c-f4316c6f9370.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00563-31 (Blood Derived Normal), aliquot CPT0065230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/713a1c84-028a-4d9c-b177-c27b756ab1e7

The open-access MAF lists 71 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Intron 4, Frame Shift Del 4, 3'UTR 3, Nonsense Mutation 3, RNA 3, Nonstop Mutation 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 158/390 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121909222, CM971270, COSV64296710, COSV64309701; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 66/169 reads (39%) | catalogued as rs121909227, CM981672, COSV64290622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADD1 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 152/430 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs747100756, COSV99295974; called by muse, mutect2, varscan2
- ARHGAP39 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1211531035; called by muse, mutect2, varscan2
- ASB4 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs747338564, COSV57507763; called by muse, mutect2
- CACNG3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770078893, COSV50068830; called by muse, mutect2, varscan2
- ENDOG | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 249/661 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs142344729; called by muse, mutect2, varscan2
- FAM228A | c.493del p.L165Ffs*18 | Frame Shift Del (DEL) | VAF 75/200 reads (38%) | catalogued as COSV54596399; called by mutect2, pindel, varscan2
- FAM71E1 | c.665G>A p.R222Q (on ENST00000600100 / NM_001308429.2; = p.R206Q on NM_138411.3) | Missense Mutation (SNP) | VAF 189/495 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.825); catalogued as rs538944264; called by muse, mutect2, varscan2
- FZD10 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV57474941; called by muse, mutect2, varscan2
- HMCN1 | c.5362C>T p.R1788C | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs773084610, COSV54876229; called by muse, mutect2
- KRT16 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 325/781 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs745882373, COSV56968644; called by muse, mutect2, varscan2
- KRT71 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs759630150; called by muse, mutect2, varscan2
- LTF | c.432G>C p.W144C | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51606657; called by muse, mutect2, varscan2
- MAGEB6 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1435965938, COSV66872352; called by muse, mutect2, varscan2
- OR52N4 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs753229074; called by muse, mutect2, varscan2
- PARP14 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221415232; called by muse, mutect2, varscan2
- PCDHGA11 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs768389351, COSV53893229; called by muse, mutect2, varscan2
- PPOX | c.745del p.V249Sfs*24 | Frame Shift Del (DEL) | VAF 100/824 reads (12%) | catalogued as COSV99237529; called by mutect2, pindel, varscan2
- RGS13 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1359297515, COSV67345566, COSV67346108, COSV67346441; called by muse, mutect2
- SKOR2 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as COSV68549959; called by muse, mutect2, varscan2
- SMG1 | c.7121G>A p.R2374Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67173308; called by muse, mutect2, varscan2
- STAT3 | c.1407G>T p.Q469H | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as CM086669; called by muse, mutect2, varscan2
- TCTEX1D1 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs200537226; called by muse, mutect2, varscan2
- THNSL1 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64480149; called by muse, mutect2, varscan2
- ZNF572 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV100073943; called by muse, mutect2, varscan2
- CCDC150 | c.1799C>G p.A600G | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CLOCK | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- COL12A1 | c.5869G>T p.A1957S | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPB41L3 | c.198A>T p.E66D | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAND2 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 176/444 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC1 | c.84T>G p.I28M | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- KCNG1 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- LRRC34 | c.1098del p.G367Dfs*9 (on ENST00000446859 / NM_001172779.2; = p.G335Dfs*9 on NM_153353.5) | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- MAGEC3 | c.1738A>G p.R580G | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MDH1 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- OFD1 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 168/444 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR3A1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 106/261 reads (41%) | called by muse, mutect2, varscan2
- PIK3R1 | c.2175A>G p.*725Wext*29 (on ENST00000521381 / NM_181523.3; = p.*455Wext*29 on NM_181504.4) | Nonstop Mutation (SNP) | VAF 22/118 reads (19%) | called by muse, varscan2
- RBMX2 | c.365A>C p.E122A | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, varscan2
- TEX13C | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 141/339 reads (42%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- USP9X | c.4386_4389del p.I1463Mfs*15 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by pindel, varscan2
- AHCY | c.726C>T p.T242= | Silent (SNP) | VAF 252/536 reads (47%) | catalogued as rs200322249, COSV54153156; called by muse, mutect2, varscan2
- FBLN2 | c.309C>T p.G103= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs959281694; called by muse, mutect2, varscan2
- GATA1 | c.594C>T p.P198= | Silent (SNP) | VAF 124/375 reads (33%) | called by muse, mutect2, varscan2
- GRID1 | c.2985C>T p.G995= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs754049968, COSV100023499, COSV60019286; called by muse, mutect2, varscan2
- HTR3E | c.1116G>A p.P372= (on ENST00000415389 / NM_001256613.1; = p.P387= on NM_182589.2) | Silent (SNP) | VAF 104/237 reads (44%) | catalogued as rs373924979; called by muse, mutect2, varscan2
- KCNK2 | c.1014C>T p.A338= (on ENST00000444842 / NM_001017425.3; = p.A323= on NM_014217.4) | Silent (SNP) | VAF 75/360 reads (21%) | catalogued as rs751828549, COSV67204020; called by muse, mutect2, varscan2
- MAN1B1 | c.945G>A p.S315= | Silent (SNP) | VAF 90/495 reads (18%) | catalogued as rs772956887; called by muse, mutect2, varscan2
- NDNF | c.252G>A p.A84= | Silent (SNP) | VAF 93/220 reads (42%) | catalogued as rs367619657, COSV65633251; called by muse, mutect2, varscan2
- OR6C4 | c.69G>C p.V23= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV67793230; called by muse, mutect2, varscan2
- SCYL3 | c.906G>A p.E302= | Silent (SNP) | VAF 36/210 reads (17%) | called by muse, mutect2, varscan2
- SERPINB10 | c.555C>T p.N185= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as rs550376818, COSV53071921; called by muse, mutect2, varscan2
- SPRR2A | c.207G>A p.P69= | Silent (SNP) | VAF 30/310 reads (10%) | catalogued as rs757443535, COSV66991261, COSV66991398; called by muse, mutect2
- TRIM32 | c.1383C>T p.C461= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as rs200244154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XKR8 | c.822C>T p.F274= | Silent (SNP) | VAF 163/390 reads (42%) | called by muse, mutect2, varscan2
- BCAR3 | c.358-21543C>T | Intron (SNP) | VAF 91/205 reads (44%) | catalogued as rs751223808; called by muse, mutect2, varscan2
- CRACD | c.*584_*585insG | 3'UTR (INS) | VAF 15/95 reads (16%) | called by mutect2, pindel
- ERICH1 | c.977-1288G>A | Intron (SNP) | VAF 82/264 reads (31%) | called by muse, mutect2, varscan2
- GUK1 | c.*11C>G | 3'UTR (SNP) | VAF 44/331 reads (13%) | catalogued as rs772161415; called by muse, mutect2, varscan2
- MIR1915 | chr10:21496753 C>T | 5'Flank (SNP) | VAF 56/265 reads (21%) | called by muse, mutect2, varscan2
- NBEAP1 | n.146A>G | RNA (SNP) | VAF 15/69 reads (22%) | catalogued as rs769647027; called by mutect2, varscan2
- PADI1 | c.*14C>T | 3'UTR (SNP) | VAF 12/392 reads (3%) | catalogued as rs747457669, COSV100968437; called by muse, mutect2
- ROBO2 | c.3935-1809C>T | Intron (SNP) | VAF 165/419 reads (39%) | catalogued as rs889107311, COSV100166210; called by muse, mutect2, varscan2
- RPL4 | c.-23C>G | 5'UTR (SNP) | VAF 70/169 reads (41%) | catalogued as rs146699571, COSV57179490; called by muse, mutect2, varscan2
- SSTR5-AS1 | n.657C>T | RNA (SNP) | VAF 29/68 reads (43%) | catalogued as rs748847969; called by muse, mutect2, varscan2
- UBE2DNL | n.221C>T | RNA (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- ZNF74 | c.121-1001C>G | Intron (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
